Somatic mutation profile of tumor specimen TCGA-B7-A5TJ-01A (aliquot TCGA-B7-A5TJ-01A-11D-A31L-08) from TCGA case TCGA-B7-A5TJ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 74.1 years (27,057 days).
Specimen TCGA-B7-A5TJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f7e6e27-e9ad-4290-b2f9-a14ac0759ed9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B7-A5TJ-10A (Blood Derived Normal), aliquot TCGA-B7-A5TJ-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b219c084-b9fa-4926-be70-baf8b49e848c

The open-access MAF lists 252 somatic variants for this specimen: 186 protein-altering or splice-affecting, 61 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 61, Frame Shift Del 11, Nonsense Mutation 10, Frame Shift Ins 4, Intron 2, Splice Region 2, 3'UTR 1, RNA 1, In Frame Del 1, 5'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.407_409del p.Q136del | In Frame Del (DEL) | VAF 36/54 reads (67%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCA12 | c.6428T>A p.I2143N (on ENST00000272895 / NM_173076.3; = p.I1825N on NM_015657.3) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99792285; called by muse, mutect2, varscan2
- ABCC4 | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as COSV100972841; called by muse, mutect2
- ABCC5 | c.2053C>A p.L685M | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657708; called by muse, mutect2, varscan2
- AC136428.1 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.302); catalogued as rs1221750724, COSV101434986; called by muse, mutect2, varscan2
- ACP2 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs4647764; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADRA1A | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs528677959, COSV52356241; called by muse, mutect2, varscan2
- AHNAK | c.16952G>A p.S5651N | Missense Mutation (SNP) | VAF 87/123 reads (71%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.958); catalogued as COSV57218521, COSV99949889; called by muse, mutect2, varscan2
- AKAP13 | c.3296G>T p.G1099V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as COSV100774788; called by muse, mutect2, varscan2
- AL035460.1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs763432652, COSV63028171; called by muse, mutect2, varscan2
- ANKRD11 | c.4891C>T p.R1631W | Missense Mutation (SNP) | VAF 119/249 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1402377065, COSV56363112; called by muse, mutect2, varscan2
- APBA2 | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.18); catalogued as COSV101382571; called by muse, mutect2, varscan2
- ARHGEF12 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 67/400 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779478124, COSV63105328; called by muse, mutect2, varscan2
- ARID2 | c.1771C>T p.Q591* | Nonsense Mutation (SNP) | VAF 8/181 reads (4%) | catalogued as COSV57617529; called by muse, mutect2
- ATP10B | c.2027A>G p.D676G | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.294); catalogued as COSV100515870; called by muse, mutect2, varscan2
- CCDC171 | c.735T>A p.H245Q | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99902175; called by muse, varscan2
- CCSER2 | c.2018C>G p.T673S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.99); catalogued as rs779996902, COSV99826603; called by muse, mutect2, varscan2
- CDH8 | c.1169del p.V390Afs*17 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as COSV54906682; called by mutect2, pindel*, varscan2
- CFTR | c.275A>T p.E92V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140308; called by muse, mutect2, varscan2
- CHRM4 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs569447371, COSV100708849, COSV63126059; called by muse, mutect2, varscan2
- CILK1 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as rs752216774, COSV100608080; called by muse, mutect2, varscan2
- CLSPN | c.1655A>T p.N552I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99231613; called by muse, mutect2
- COL4A5 | c.3025G>A p.G1009S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100090231; called by muse, mutect2
- COL6A3 | c.8576C>T p.P2859L | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1050010905, COSV55079894; called by muse, mutect2, varscan2
- CXorf58 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191542694, COSV101003125, COSV64858528; called by muse, mutect2
- CYP4F8 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as COSV100358268; called by muse, mutect2
- DAP3 | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 108/190 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100546681; called by muse, mutect2, varscan2
- DNAH5 | c.8770G>A p.A2924T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs748993870, COSV54205191; called by muse, mutect2, varscan2
- DPYSL2 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs752044385, COSV100234275; called by muse, mutect2, varscan2
- DSTYK | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.394); catalogued as rs573628666, COSV100904599, COSV100904744; called by muse, mutect2, varscan2
- EDNRB | c.286A>G p.S96G (on ENST00000377211 / NM_001201397.1; = p.S6G on NM_000115.5) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.167); catalogued as COSV100527161; called by muse, mutect2
- EDNRB | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV57521250; called by muse, mutect2, varscan2
- EMCN | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99598771; called by muse, mutect2, varscan2
- ENAH | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious, low confidence (0); catalogued as rs148381397; called by muse, mutect2, varscan2
- FADD | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100096777; called by muse, mutect2
- FAM135B | c.1425A>C p.E475D | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99417889, COSV99427864; called by muse, mutect2
- FAM237A | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); catalogued as COSV101405604; called by muse, mutect2
- FAM83H | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1363134701, COSV66354507; called by muse, mutect2
- FAT2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201874812, COSV55828205; called by muse, mutect2, varscan2
- FAT3 | c.5335A>G p.S1779G | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53121540, COSV99971661; called by muse, mutect2
- FOXB2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.018); catalogued as COSV100942401, COSV99060462; called by muse, mutect2, varscan2
- FOXK1 | c.457T>G p.F153V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as COSV100195927; called by muse, mutect2, varscan2
- FRMD4A | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs376872935, COSV52726372; called by muse, mutect2, varscan2
- FYCO1 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1237180696, COSV56118376; called by muse, mutect2
- GAL3ST3 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100361000; called by muse, mutect2, varscan2
- GFRA3 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.546); catalogued as COSV51228876; called by muse, mutect2
- GGTLC1 | c.272T>A p.V91E | Missense Mutation (SNP) | VAF 166/333 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV99600972; called by muse, mutect2, varscan2
- GIGYF2 | c.3844A>G p.N1282D | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV101004632; called by muse, mutect2
- GJA10 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 112/168 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101005458; called by muse, mutect2, varscan2
- GPR149 | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101078786; called by muse, mutect2, varscan2
- HAPLN4 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs374285172; called by muse, mutect2, varscan2
- HCN1 | c.676T>G p.F226V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV100302599; called by muse, mutect2, varscan2
- HEPHL1 | c.2618G>A p.G873D | Missense Mutation (SNP) | VAF 56/80 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100244475; called by muse, mutect2, varscan2
- HMCN1 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.965); catalogued as COSV99636718; called by muse, mutect2
- HTR1F | c.31T>G p.L11V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100138195, COSV60389317; called by muse, mutect2, varscan2
- IFIT2 | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV99261053; called by muse, mutect2, varscan2
- ITGA9 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs201919539, COSV53242240; called by muse, mutect2, varscan2
- JMJD4 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs751630183, COSV59921275; called by muse, mutect2, varscan2
- KAT14 | c.488dup p.L163Ffs*5 | Frame Shift Ins (INS) | VAF 21/207 reads (10%) | catalogued as rs1480801806; called by mutect2, pindel
- KCNC1 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1167748453, COSV56393797; called by muse, mutect2, varscan2
- KCND2 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.862); catalogued as rs761446789, COSV58602956; called by muse, mutect2
- KCNH5 | c.1788A>C p.E596D | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528346, COSV100528658; called by muse, mutect2, varscan2
- KCNT2 | c.2885A>G p.E962G | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs780063690, COSV54075109, COSV99657123; called by muse, mutect2, varscan2
- KDM2A | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100445860; called by muse, mutect2, varscan2
- KDM3B | c.3158G>A p.C1053Y | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100070304, COSV58689448; called by muse, mutect2, varscan2
- KDM5B | c.3082C>T p.Q1028* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV99351501; called by muse, mutect2
- KIF20B | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53316837, COSV99590830; called by muse, mutect2, varscan2
- KLF4 | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV65929698; called by muse, mutect2, varscan2
- KMT2A | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 31/195 reads (16%) | catalogued as COSV63284566; called by muse, mutect2, varscan2
- LRFN1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs760009961, COSV50499311; called by muse, mutect2, varscan2
- LRRC73 | c.684C>A p.Y228* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as COSV99447623; called by muse, mutect2
- MAP1A | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs369443962; called by muse, mutect2, varscan2
- MAT2B | c.691T>C p.C231R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV99796991; called by muse, mutect2, varscan2
- MICALL1 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1006475452, COSV53240783; called by muse, mutect2, varscan2
- MKI67 | c.4633G>A p.V1545I | Missense Mutation (SNP) | VAF 11/321 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); catalogued as COSV100897035; called by muse, mutect2
- MRE11 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100120126; called by muse, mutect2, varscan2
- MRGPRX3 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 106/160 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0.326); catalogued as COSV101283591; called by muse, mutect2, varscan2
- MUC16 | c.21930T>G p.I7310M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV101201918; called by muse, mutect2, varscan2
- MUC16 | c.15847A>G p.T5283A | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as COSV101201919; called by muse, mutect2
- MYH2 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs141174023, COSV55437252; called by muse, mutect2, varscan2
- MYOM2 | c.3940C>T p.R1314C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142380219; called by muse, mutect2, varscan2
- NAV1 | c.3302C>T p.T1101M | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99819809; called by muse, mutect2, varscan2
- NBEAL2 | c.5276G>A p.R1759H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs778796443, COSV52759887; called by muse, mutect2, varscan2
- NDUFB5 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV99372685; called by muse, mutect2, varscan2
- NFASC | c.358G>A p.A120T (on ENST00000339876 / NM_001378329.1; = p.A114T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771183209, COSV58358391; called by muse, mutect2, varscan2
- NLGN4X | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV99324234; called by muse, mutect2, varscan2
- NOS1 | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as rs371044828; called by muse, mutect2, varscan2
- NR2F1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as COSV59067745; called by muse, mutect2, varscan2
- NRK | c.1445A>G p.Q482R | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV54602677; called by muse, mutect2, varscan2
- NRXN3 | c.335G>A p.R112H (on ENST00000557594 / NM_001272020.2; = p.R744H on NM_004796.6) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1265485518, COSV55317985; called by muse, mutect2, varscan2
- NTNG1 | c.186A>T p.K62N | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.399); catalogued as COSV99639814; called by muse, mutect2, varscan2
- NUP210 | c.4306G>A p.G1436R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.863); catalogued as rs375252151, COSV99596606; called by muse, mutect2, varscan2
- NXF3 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101222087; called by muse, mutect2
- OLFM3 | c.529A>C p.I177L (on ENST00000338858 / NM_001288821.1; = p.I157L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100130189; called by muse, mutect2, varscan2
- OLFML2A | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.095); catalogued as COSV99992928; called by muse, mutect2
- OR2A42 | c.313A>G p.S105G | Missense Mutation (SNP) | VAF 73/119 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101195849; called by muse, mutect2, varscan2
- OR2M5 | c.418A>C p.I140L | Missense Mutation (SNP) | VAF 111/425 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV63545771, COSV63547046; called by muse, varscan2
- OR2W3 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 154/307 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100831867; called by muse, mutect2, varscan2
- OR4D2 | c.853A>T p.M285L | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101613869; called by muse, mutect2
- OR5H15 | c.693T>A p.D231E | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1197070892, COSV100736783; called by muse, mutect2
- OTUD7B | c.1444G>A p.G482S | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs369849263; called by muse, mutect2
- P2RY8 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV101184206; called by muse, mutect2, varscan2
- PABPC3 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV55803028, COSV55806926; called by muse, mutect2
- PABPC5 | c.653T>G p.L218R | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100442641, COSV100442711, COSV57041660; called by muse, mutect2, varscan2
- PCDH8 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV100132091; called by muse, mutect2
- PCDH9 | c.3478A>C p.T1160P (on ENST00000377865 / NM_203487.3; = p.T1126P on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/219 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100124023; called by muse, mutect2, varscan2
- PCDHAC2 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV99163417; called by muse, mutect2, varscan2
- PCDHB10 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53382424; called by muse, mutect2
- PCDHGA1 | c.1941G>T p.Q647H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV100966138; called by muse, mutect2, varscan2
- PCDHGA1 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); catalogued as rs762152002, COSV65299810; called by muse, mutect2, varscan2
- PEG3 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.222); catalogued as rs754473044, COSV55631785; called by muse, mutect2, varscan2
- PHLPP1 | c.2828G>A p.R943Q | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1433579204, COSV99409403; called by muse, mutect2
- PI4KA | c.4324G>A p.V1442I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.035); catalogued as COSV99748889; called by muse, mutect2, varscan2
- PLEK | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 104/214 reads (49%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.991); catalogued as COSV52250717, COSV99311275; called by muse, mutect2, varscan2
- PON3 | c.121A>T p.N41Y | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV99672763; called by muse, mutect2, varscan2
- PREX2 | c.2654T>G p.F885C | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1444459184, COSV99910331; called by muse, mutect2, varscan2
- PRF1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs201468340, CM071927, CX151487, COSV64615741; called by muse, mutect2, varscan2
- PROX1 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.182); catalogued as rs777612764, COSV99800320; called by muse, mutect2, varscan2
- PTBP1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV100609179; called by muse, mutect2
- PUS3 | c.468A>C p.E156D | Missense Mutation (SNP) | VAF 150/194 reads (77%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV99917107; called by muse, mutect2, varscan2
- PXDN | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs778748288, COSV53225794; called by muse, mutect2, varscan2
- PYGO2 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.712); catalogued as rs978407418, COSV100868999, COSV63756955; called by muse, mutect2, varscan2
- PZP | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs779959248, COSV54354958, COSV54365221; called by muse, mutect2, varscan2
- RAE1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 20/191 reads (10%) | catalogued as COSV100982498; called by muse, mutect2, varscan2
- RASA3 | c.2207T>G p.L736R | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100481274; called by muse, mutect2
- RBM10 | c.2100G>A p.K700= | Splice Region (SNP) | VAF 21/30 reads (70%) | catalogued as COSV100238372; called by muse, mutect2, varscan2
- RETNLB | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV55465742; called by muse, mutect2, varscan2
- RFX7 | c.3424G>A p.A1142T (on ENST00000559447 / NM_001368074.1; = p.A1239T on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1293190919, COSV57967936; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 32/189 reads (17%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPS15 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV99245535; called by muse, mutect2, varscan2
- RPTN | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 41/1054 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs760842504, COSV60167149; called by muse, mutect2
- RUSC1 | c.1998G>C p.E666D (on ENST00000368352 / NM_001105203.2; = p.E197D on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99430347; called by muse, mutect2
- SAMSN1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746815653, COSV53467361, COSV53478772; called by muse, mutect2, varscan2
- SCARA5 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs756374530, COSV57276967; called by muse, varscan2
- SETBP1 | c.654C>A p.N218K | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV99955222; called by muse, mutect2, varscan2
- SGCE | c.1143C>T p.G381= (on ENST00000647096; = p.G345= on NM_003919.3) | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as rs1258484610, COSV99722976; called by muse, mutect2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs747473028; called by mutect2, varscan2
- SHISA2 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs769814800, COSV100096652; called by muse, mutect2
- SLC44A4 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99999334; called by muse, mutect2, varscan2
- SLC5A9 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV99362046; called by muse, mutect2, varscan2
- SORCS3 | c.2138G>T p.C713F | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100863872; called by muse, mutect2
- SPANXD | c.137A>G p.E46G | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV65152418; called by muse, mutect2, varscan2
- STXBP5L | c.1015A>C p.S339R | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV56511827; called by muse, mutect2, varscan2
- SYNPO | c.2702G>A p.R901Q (on ENST00000394243 / NM_001166208.2; = p.R657Q on NM_007286.6) | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs915401572, COSV100302478; called by muse, mutect2, varscan2
- SYNPO2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs540880651, COSV100206487; called by muse, mutect2, varscan2
- TECTA | c.3851G>A p.R1284H | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.475); catalogued as rs141717375, COSV50694342; called by muse, mutect2, varscan2
- TEX10 | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 85/203 reads (42%) | catalogued as COSV100887980; called by muse, mutect2, varscan2
- TMEM132A | c.1442G>A p.R481Q (on ENST00000453848 / NM_178031.3; = p.R482Q on NM_017870.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV99137361; called by muse, mutect2, varscan2
- TMEM182 | c.399G>T p.L133F | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV101305430; called by muse, mutect2, varscan2
- TNFSF8 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.388); catalogued as rs926790345, COSV99802147; called by muse, mutect2, varscan2
- TRAPPC9 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs892180852, COSV101227056, COSV66896432; called by muse, mutect2, varscan2
- TRIB2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as rs758793068, COSV99331092; called by muse, mutect2, varscan2
- TRIM31 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 45/193 reads (23%) | catalogued as rs867386342, COSV65060018; called by muse, mutect2, varscan2
- TSHZ2 | c.864A>C p.Q288H | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100296849; called by muse, mutect2
- TTN | c.73922A>C p.K24641T (on ENST00000591111; = p.K17217T on NM_003319.4) | Missense Mutation (SNP) | VAF 119/241 reads (49%) | PolyPhen benign (0.439); catalogued as COSV100632861; called by muse, mutect2, varscan2
- TTN | c.25433A>C p.Q8478P (on ENST00000591111; = p.Q7551P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/92 reads (5%) | PolyPhen benign (0.411); catalogued as COSV100632862; called by muse, mutect2
- TUBB6 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.83); catalogued as COSV99302225; called by muse, mutect2
- USH2A | c.13367G>A p.G4456D | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV100243335; called by muse, mutect2, varscan2
- USH2A | c.2603G>A p.C868Y | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56342095; called by muse, mutect2, varscan2
- VCX3A | c.516A>C p.E172D | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.818); catalogued as COSV101129987; called by muse, varscan2
- WNT11 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1175520048, COSV59443452; called by muse, mutect2, varscan2
- YARS2 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767331277, COSV100256564; called by muse, mutect2, varscan2
- ZDBF2 | c.1057T>G p.F353V | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100985622, COSV65628745; called by muse, mutect2, varscan2
- ZMYND15 | c.1520_1523del p.K507Sfs*3 (on ENST00000433935 / NM_001136046.3; = p.K468Sfs*3 on NM_032265.2) | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs587777432; called by pindel, varscan2
- ZNF429 | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.061); catalogued as rs368726828; called by muse, varscan2
- ZNF586 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV101197753; called by muse, mutect2, varscan2
- ZNF611 | c.1568C>G p.S523* | Nonsense Mutation (SNP) | VAF 10/174 reads (6%) | catalogued as COSV100160568; called by muse, mutect2
- ZNF611 | c.1131A>C p.K377N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100160673; called by muse, mutect2, varscan2
- ZNF765 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1168995021, COSV101125406, COSV101125586; called by muse, mutect2, varscan2
- ZNF768 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.231); catalogued as rs1283662261, COSV100776375; called by muse, mutect2, varscan2
- ZNF816 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99554736; called by muse, mutect2, varscan2
- ZSWIM4 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs781655188, COSV54326741; called by muse, mutect2, varscan2
- ATP5PB | c.345dup p.Y116Ifs*10 | Frame Shift Ins (INS) | VAF 30/93 reads (32%) | called by mutect2, pindel, varscan2
- CARD10 | c.1937_1942dup p.P647_R648insKP | In Frame Ins (INS) | VAF 62/225 reads (28%) | called by mutect2, pindel, varscan2
- FAM162B | c.423_430del p.W141Cfs*5 | Frame Shift Del (DEL) | VAF 33/177 reads (19%) | called by mutect2, pindel, varscan2
- FZR1 | c.1124del p.G375Afs*14 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- HMCN1 | c.407_414dup p.I139Vfs*36 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | called by mutect2, varscan2
- IGHE | c.1104C>G p.D368E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOM3 | c.2947dup p.S983Kfs*18 | Frame Shift Ins (INS) | VAF 9/91 reads (10%) | called by mutect2, pindel
- NDST4 | c.756_757del p.F253Cfs*11 | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | called by pindel, varscan2
- SIPA1L3 | c.983del p.P328Rfs*78 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- USP32 | c.1277del p.L426* | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | called by mutect2, pindel, varscan2
- WASHC2A | c.3427C>T p.Q1143* | Nonsense Mutation (SNP) | VAF 32/157 reads (20%) | called by muse, mutect2, varscan2
- ZMYM4 | c.4340_4344del p.N1447Rfs*2 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- ABCA3 | c.1335C>T p.D445= | Silent (SNP) | VAF 99/305 reads (32%) | catalogued as rs147185732, COSV100069179; called by muse, mutect2, varscan2
- ADGRL4 | c.1788T>G p.V596= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100876587; called by muse, mutect2, varscan2
- AK3 | c.84T>A p.T28= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100729559; called by muse, mutect2
- ALDH1L1 | c.1566C>T p.H522= | Silent (SNP) | VAF 15/230 reads (7%) | catalogued as rs573922345, COSV99857592; called by muse, mutect2
- CAVIN2 | c.591G>T p.L197= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100414358; called by muse, mutect2, varscan2
- CCDC171 | c.3783C>T p.S1261= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV101048885; called by muse, mutect2
- CCKBR | c.870C>T p.S290= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as rs1220407751, COSV58099304; called by muse, mutect2, varscan2
- CDC25B | c.1107C>T p.R369= (on ENST00000245960 / NM_021873.3; = p.R355= on NM_004358.4) | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs143612466; called by muse, mutect2, varscan2
- CDH8 | c.309T>C p.D103= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100184400; called by muse, mutect2, varscan2
- CFL2 | c.378G>A p.K126= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV104402384, COSV99990633; called by muse, mutect2, varscan2
- CHD1 | c.3726C>T p.C1242= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV99399981; called by muse, mutect2
- CNTN3 | c.2604C>T p.G868= | Silent (SNP) | VAF 11/164 reads (7%) | catalogued as COSV99726249; called by muse, mutect2
- COL11A1 | c.3714A>C p.P1238= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as COSV100617019, COSV62202819; called by muse, mutect2, varscan2
- CSMD1 | c.6555T>G p.V2185= (on ENST00000520002; = p.V2184= on NM_033225.6) | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV59278659; called by muse, mutect2, varscan2
- DISC1 | c.1536C>A p.S512= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99697738, COSV99698803; called by muse, mutect2, varscan2
- DTNA | c.1776C>T p.D592= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as rs1437954707, COSV99315744; called by muse, mutect2, varscan2
- ERICH3 | c.1974G>A p.P658= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs774666353, COSV100444877; called by muse, mutect2, varscan2
- FAM222B | c.942C>T p.S314= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs747372365, COSV100368757; called by muse, mutect2, varscan2
- GAL3ST2 | c.222C>T p.F74= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs144819363; called by muse, mutect2, varscan2
- GLI3 | c.2736C>T p.S912= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs752024375, COSV67887762; called by muse, mutect2, varscan2
- GNRHR | c.702C>A p.I234= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99892393; called by muse, mutect2, varscan2
- GPRIN2 | c.288C>A p.G96= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV100966313, COSV100966515; called by muse, mutect2
- GTF2IRD1 | c.261C>T p.F87= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV99735682; called by muse, mutect2
- GTF2IRD1 | c.2508C>T p.D836= (on ENST00000265755 / NM_016328.3; = p.D821= on NM_005685.4) | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as rs782103952, COSV56085397; called by muse, mutect2
- ITGA2 | c.2214C>T p.P738= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs142557473, COSV56861303, COSV99670329; called by muse, mutect2, varscan2
- KLHL38 | c.1278C>T p.V426= | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as rs761928204, COSV58089512; called by muse, mutect2, varscan2
- MAGEC1 | c.2808G>T p.T936= | Silent (SNP) | VAF 85/117 reads (73%) | catalogued as COSV53577513, COSV99596688; called by muse, mutect2, varscan2
- MARK4 | c.648C>T p.C216= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as rs1369488450, COSV53465566; called by muse, mutect2
- MBOAT2 | c.1095G>A p.T365= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs777596737, COSV100019619; called by muse, mutect2, varscan2
- MCM3AP | c.5364T>C p.V1788= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV99387595; called by muse, mutect2, varscan2
- MYLK | c.4656C>T p.D1552= | Silent (SNP) | VAF 36/162 reads (22%) | catalogued as rs749367561, COSV100659737; called by muse, mutect2, varscan2
- MYOM2 | c.1215G>A p.P405= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs563008335, COSV50754142; called by muse, mutect2, varscan2
- NRG1 | c.1095C>T p.S365= (on ENST00000405005 / NM_013964.5; = p.S370= on NM_013956.5) | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as rs772910330, COSV99829776; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUP188 | c.1803G>A p.T601= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV65365325; called by muse, mutect2
- OR2L3 | c.744T>G p.T248= | Silent (SNP) | VAF 24/202 reads (12%) | catalogued as COSV63455722, COSV63455810; called by muse, mutect2, varscan2
- OR4A47 | c.207C>A p.I69= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV101487117, COSV71444842; called by muse, mutect2, varscan2
- OR52A5 | c.192T>C p.F64= | Silent (SNP) | VAF 67/81 reads (83%) | catalogued as COSV100263585; called by muse, mutect2, varscan2
- OR5K4 | c.501T>G p.T167= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100721418; called by muse, mutect2, varscan2
- PBLD | c.735G>A p.L245= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as COSV99516261; called by muse, mutect2, varscan2
- PDZD4 | c.1464C>T p.P488= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99381698; called by mutect2, varscan2
- PGA3 | c.447C>T p.D149= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100337300; called by mutect2, varscan2
- PPP1R13L | c.1392G>A p.P464= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs767546785, COSV62908389; called by muse, mutect2, varscan2
- PRRC2A | c.3030G>A p.R1010= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV101051396, COSV65685578; called by muse, mutect2, varscan2
- RAB40A | c.21C>T p.P7= | Silent (SNP) | VAF 42/61 reads (69%) | catalogued as rs746260784, COSV100421027, COSV100421037; called by muse, mutect2, varscan2
- RALGAPB | c.957G>A p.P319= | Silent (SNP) | VAF 35/252 reads (14%) | catalogued as rs146906566; called by muse, mutect2, varscan2
- RBM11 | c.813G>A p.K271= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs1027917939, COSV101271248; called by muse, mutect2, varscan2
- RIMS1 | c.211A>C p.R71= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs980106766, COSV53441304, COSV53444045, COSV53451865; called by muse, mutect2
- SERGEF | c.1002A>T p.G334= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99787909; called by muse, varscan2
- SLC17A9 | c.522C>T p.G174= | Silent (SNP) | VAF 79/300 reads (26%) | catalogued as COSV100948016; called by muse, mutect2, varscan2
- SLC39A5 | c.999G>A p.E333= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV99907697; called by muse, mutect2, varscan2
- SPATC1 | c.1038C>T p.A346= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV101085380; called by muse, mutect2, varscan2
- TFAP2A | c.1098C>T p.P366= (on ENST00000482890; = p.P358= on NM_001032280.3) | Silent (SNP) | VAF 19/418 reads (5%) | catalogued as COSV100117224; called by muse, mutect2
- TGM4 | c.1590G>A p.S530= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs528006561, COSV99942370; called by muse, mutect2, varscan2
- THSD7B | c.2700A>G p.K900= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV99758775; called by muse, mutect2, varscan2
- TMPRSS15 | c.1155T>G p.T385= | Silent (SNP) | VAF 72/118 reads (61%) | catalogued as COSV53034369, COSV99516712; called by muse, mutect2, varscan2
- TRPA1 | c.837T>C p.A279= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100085357; called by muse, mutect2, varscan2
- TRPM3 | c.3543C>T p.Y1181= (on ENST00000357533 / NM_001366142.2; = p.Y1036= on NM_020952.6) | Silent (SNP) | VAF 75/362 reads (21%) | catalogued as rs755939569, COSV62585329; called by muse, mutect2, varscan2
- TTN | c.64707C>T p.Y21569= (on ENST00000591111; = p.Y14145= on NM_003319.4) | Silent (SNP) | VAF 51/240 reads (21%) | catalogued as rs777602537, CM1514597, COSV100600284; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZDHHC1 | c.1239G>T p.G413= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99339591; called by muse, mutect2, varscan2
- ZDHHC3 | c.882G>A p.P294= (on ENST00000424952 / NM_001135179.2; = p.P322= on NM_016598.3) | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs377350770, COSV56103391; called by muse, mutect2, varscan2
- ZFHX4 | c.10482C>T p.V3494= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV99268440; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840636 G>A | 5'Flank (SNP) | VAF 16/82 reads (20%) | catalogued as rs1568908369, COSV58342712; called by muse, mutect2, varscan2
- GABRA1 | c.*1A>T | 3'UTR (SNP) | VAF 5/79 reads (6%) | catalogued as COSV99196327; called by muse, mutect2
- SNORD115-30 | n.20T>C | RNA (SNP) | VAF 70/232 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.10361-3964dup | Intron (INS) | VAF 34/167 reads (20%) | catalogued as rs1560961746; called by mutect2, varscan2
- TTN | c.10360+1253T>G | Intron (SNP) | VAF 72/152 reads (47%) | catalogued as COSV59861821, COSV59870423; called by muse, mutect2, varscan2
